Somatic mutation profile of tumor specimen TCGA-97-8179-01A (aliquot TCGA-97-8179-01A-11D-2284-08) from TCGA case TCGA-97-8179, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.0 years (26,305 days).
Specimen TCGA-97-8179-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28b9cae0-7690-45dd-8b5d-3a703a86cfe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8179-10A (Blood Derived Normal), aliquot TCGA-97-8179-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d43ef3c0-ed72-4133-be6e-0a00c8cda220

The open-access MAF lists 188 somatic variants for this specimen: 140 protein-altering or splice-affecting, 39 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 39, Nonsense Mutation 9, Frame Shift Del 7, RNA 5, Splice Site 3, Intron 3, Frame Shift Ins 2, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 22/38 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 44/69 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AK9 | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV99572281; called by muse, mutect2, varscan2
- AMER3 | c.144C>A p.H48Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100365901; called by muse, mutect2, varscan2
- ANAPC16 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as COSV100191794; called by muse, mutect2, varscan2
- ANKRD34B | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58613778; called by muse, mutect2, varscan2
- BOLL | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as COSV99986807; called by muse, mutect2, varscan2
- BRDT | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100746056, COSV62865118; called by muse, mutect2, varscan2
- CACNB2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as COSV99992619; called by muse, mutect2, varscan2
- CASS4 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as COSV100824504; called by muse, mutect2, varscan2
- CCDC89 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 120/229 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100320786; called by muse, mutect2, varscan2
- CFHR4 | c.1733A>C p.*578Sext*27 (on ENST00000367416 / NM_001201551.2; = p.*332Sext*27 on NM_006684.5) | Nonstop Mutation (SNP) | VAF 90/359 reads (25%) | catalogued as COSV99259362; called by muse, mutect2, varscan2
- CHRM2 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100280576; called by muse, mutect2, varscan2
- CLCA2 | c.2147C>A p.T716K | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100991299; called by muse, mutect2, varscan2
- CLCN1 | c.1326C>A p.S442R | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.295); catalogued as COSV100577627; called by muse, mutect2, varscan2
- CLCN1 | c.2411C>A p.A804D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.818); catalogued as COSV100577631; called by muse, mutect2
- CLSTN2 | c.1784C>A p.T595K | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101515431; called by muse, mutect2, varscan2
- CNGB3 | c.1478T>A p.L493Q | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100181052; called by muse, mutect2, varscan2
- CNTN5 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV54307565, COSV99671966; called by muse, mutect2, varscan2
- COL5A2 | c.2869G>T p.G957* | Nonsense Mutation (SNP) | VAF 44/119 reads (37%) | catalogued as COSV100879938; called by muse, mutect2, varscan2
- COLEC12 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1472931515, COSV101231916; called by muse, mutect2, varscan2
- CPXM2 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99580782; called by muse, mutect2, varscan2
- DCAF12L1 | c.1322T>A p.M441K | Missense Mutation (SNP) | VAF 130/193 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100948050; called by muse, varscan2
- DCAF12L1 | c.1251G>T p.W417C | Missense Mutation (SNP) | VAF 108/180 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100948051; called by muse, varscan2
- DDX27 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV100874631; called by muse, mutect2, varscan2
- DNAJC22 | c.110C>A p.T37N | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1375861449, COSV101222493; called by muse, mutect2, varscan2
- DRD2 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV60757879; called by muse, varscan2
- DRD3 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 112/217 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99879104; called by muse, mutect2, varscan2
- DUOXA1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 109/212 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177010321, COSV99972712; called by muse, mutect2, varscan2
- DYNC1I1 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100267445, COSV61468266; called by muse, mutect2, varscan2
- DYNC1I1 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 177/539 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100267447, COSV61459978; called by muse, mutect2, varscan2
- ETS2 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV62874739; called by muse, mutect2, varscan2
- FAM135B | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 129/505 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99417748; called by muse, mutect2, varscan2
- FAM181B | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as COSV100234990; called by muse, mutect2, varscan2
- FBLN2 | c.1920T>A p.D640E | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99851256; called by muse, mutect2, varscan2
- FREM2 | c.7042A>T p.I2348L | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV99746338; called by muse, mutect2, varscan2
- GABBR2 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99408950; called by muse, mutect2, varscan2
- GCC2 | c.2890G>T p.E964* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100565181; called by muse, mutect2, varscan2
- GLG1 | c.3340G>T p.D1114Y | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV99215182; called by muse, mutect2
- GOLIM4 | c.432A>C p.E144D | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV100462576; called by muse, mutect2, varscan2
- GPC6 | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100987950, COSV100989388; called by muse, mutect2, varscan2
- GRAP2 | c.690G>C p.Q230H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV100702869, COSV59997377; called by muse, mutect2, varscan2
- GREB1 | c.2941G>T p.E981* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99302065; called by muse, mutect2, varscan2
- GRIA4 | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 81/139 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99228262; called by muse, mutect2, varscan2
- HELQ | c.1366A>G p.S456G | Missense Mutation (SNP) | VAF 127/237 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99787347; called by muse, mutect2, varscan2
- HIVEP3 | c.6653C>T p.T2218I | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99911241; called by muse, mutect2, varscan2
- HP | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100577435; called by muse, mutect2, varscan2
- HPGD | c.294A>C p.K98N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.211); catalogued as COSV99640039; called by muse, mutect2, varscan2
- INPP4B | c.2135+1G>A p.X712_splice | Splice Site (SNP) | VAF 60/119 reads (50%) | catalogued as COSV53745809; called by muse, mutect2, varscan2
- ITGAM | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99791658; called by muse, mutect2, varscan2
- ITGB4 | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 169/287 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs530031041, COSV99563172; called by muse, mutect2, varscan2
- KCNJ1 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131201; called by muse, mutect2, varscan2
- KCNMB1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51131505, COSV99210344; called by muse, mutect2, varscan2
- KIAA0100 | c.6578G>T p.G2193V | Missense Mutation (SNP) | VAF 155/245 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as rs762162603, COSV99971884; called by muse, mutect2, varscan2
- KRTAP19-3 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 214/707 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as rs1177468683, COSV61854629; called by muse, mutect2, varscan2
- KRTAP21-1 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.04); catalogued as rs767818259; called by muse, mutect2, varscan2
- LAMB2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100564946; called by muse, mutect2, varscan2
- LIN7A | c.543C>A p.S181R | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs781184338, COSV99691622; called by muse, mutect2, varscan2
- LPAR4 | c.995C>A p.S332Y | Missense Mutation (SNP) | VAF 128/188 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV101425067; called by muse, mutect2, varscan2
- LRRC7 | c.1129A>T p.R377* (on ENST00000651989 / NM_001370785.2; = p.R344* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV50565184, COSV99224038; called by muse, mutect2, varscan2
- LTBP1 | c.1316T>C p.V439A (on ENST00000404816 / NM_206943.4; = p.V113A on NM_000627.4) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100616139; called by muse, mutect2, varscan2
- LTBP2 | c.1136C>A p.T379N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99999520; called by muse, mutect2, varscan2
- LUC7L | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as COSV99550940; called by muse, mutect2, varscan2
- MAGI1 | c.2677G>C p.V893L (on ENST00000402939 / NM_001033057.2; = p.V921L on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV100439020, COSV58348499; called by muse, mutect2, varscan2
- MDM1 | c.1415G>T p.R472M | Missense Mutation (SNP) | VAF 252/514 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV57445694; called by muse, mutect2, varscan2
- MSLN | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1451600280, COSV99557853; called by muse, mutect2, varscan2
- MUC16 | c.25519G>T p.E8507* | Nonsense Mutation (SNP) | VAF 151/281 reads (54%) | catalogued as COSV101197663; called by muse, mutect2, varscan2
- MUC16 | c.9637G>T p.E3213* | Nonsense Mutation (SNP) | VAF 123/207 reads (59%) | catalogued as COSV101197664, COSV67467593; called by muse, mutect2, varscan2
- MYH3 | c.4720G>C p.D1574H | Missense Mutation (SNP) | VAF 234/389 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56869129; called by muse, mutect2, varscan2
- NCBP2 | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV100343626; called by muse, mutect2, varscan2
- NCS1 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100969856; called by muse, mutect2, varscan2
- NEK1 | c.2431G>C p.V811L | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV101455584; called by muse, mutect2, varscan2
- NETO2 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as COSV100292333; called by muse, mutect2, varscan2
- NLGN4X | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.68); catalogued as COSV52024532, COSV99319545; called by muse, mutect2, varscan2
- NRXN1 | c.3376T>A p.Y1126N | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100452783; called by muse, mutect2, varscan2
- NRXN1 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs751232467, COSV101276240; called by muse, mutect2, varscan2
- NRXN3 | c.1474C>A p.Q492K (on ENST00000335750 / NM_001330195.2; = p.Q119K on NM_004796.6) | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV100199934; called by muse, mutect2, varscan2
- NUP205 | c.5860A>G p.I1954V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs201103102, COSV99606347; called by muse, mutect2, varscan2
- NUTM1 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV100412020; called by muse, mutect2
- OBSL1 | c.3134G>T p.R1045L | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54707421, COSV99216035; called by muse, mutect2, varscan2
- OR10A2 | c.793T>A p.Y265N | Missense Mutation (SNP) | VAF 157/293 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100224906; called by muse, mutect2, varscan2
- OR2T33 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 273/665 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs1462270189, COSV100531504; called by muse, mutect2, varscan2
- OR4A16 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 176/356 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as COSV59045069; called by muse, mutect2, varscan2
- PCDH18 | c.1744C>A p.R582S | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs200901920, COSV100786961, COSV61267797; called by muse, mutect2, varscan2
- PCDHA5 | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.438); catalogued as COSV100972058, COSV65355449; called by muse, mutect2, varscan2
- PCDHB3 | c.1768G>T p.V590L | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99164113; called by muse, mutect2, varscan2
- PCDHGA6 | c.2424G>T p.Q808H | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99529023; called by muse, mutect2, varscan2
- PDCD1 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100545284; called by muse, mutect2, varscan2
- PDHA2 | c.517G>C p.A173P | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99756366; called by muse, mutect2, varscan2
- PIK3CG | c.2800G>T p.G934C | Missense Mutation (SNP) | VAF 145/386 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100782448, COSV63254963; called by muse, mutect2, varscan2
- PLSCR1 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.223); catalogued as rs781333741, COSV100678267; called by muse, mutect2, varscan2
- PNO1 | c.441+2T>A p.X147_splice | Splice Site (SNP) | VAF 43/88 reads (49%) | catalogued as COSV99718112; called by muse, mutect2, varscan2
- PRSS58 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 122/335 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV101616075; called by muse, mutect2, varscan2
- PSMB11 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV101273393, COSV101273435; called by muse, mutect2, varscan2
- PTF1A | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 327/736 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV100919557; called by muse, mutect2, varscan2
- PTK7 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.499); catalogued as rs150064108, COSV100029760, COSV57847973; called by muse, mutect2, varscan2
- RAB29 | c.47C>G p.A16G | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99352885; called by muse, mutect2, varscan2
- RABEP1 | c.2050T>A p.Y684N | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV99336191; called by muse, mutect2
- RABGGTA | c.1303G>T p.V435L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99252680; called by muse, mutect2, varscan2
- RIN2 | c.1064_1065insA p.P358Tfs*9 (on ENST00000255006 / NM_001242581.1; = p.P309Tfs*9 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 50/137 reads (36%) | catalogued as COSV99656551; called by mutect2, pindel, varscan2
- RYR2 | c.851G>T p.W284L | Missense Mutation (SNP) | VAF 77/359 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV63677056, COSV63679342; called by muse, mutect2, varscan2
- RYR2 | c.852G>T p.W284C | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100767323; called by muse, mutect2, varscan2
- SCAF8 | c.783+2T>C p.X261_splice | Splice Site (SNP) | VAF 33/70 reads (47%) | catalogued as COSV100913860; called by muse, varscan2
- SDK2 | c.3245C>G p.P1082R | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as COSV101166598, COSV66192566; called by muse, mutect2, varscan2
- SEC24D | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs764418396, COSV99755265; called by muse, mutect2, varscan2
- SEMG1 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99725028; called by muse, mutect2, varscan2
- SIAH1 | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV99588751; called by muse, mutect2, varscan2
- SLC24A1 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV56051563; called by muse, mutect2
- SLC28A2 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100754580; called by muse, mutect2, varscan2
- SLC43A2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100024627; called by muse, mutect2, varscan2
- SLC6A5 | c.248G>T p.S83I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV100116310; called by muse, mutect2, varscan2
- SLC7A4 | c.1535T>A p.L512Q | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100298483; called by muse, mutect2, varscan2
- SPTA1 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934088; called by muse, mutect2, varscan2
- SRMS | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV99421078; called by muse, mutect2, varscan2
- SRPK3 | c.1007C>A p.P336H | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99472885; called by muse, mutect2, varscan2
- STYXL1 | c.707A>G p.H236R | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99951203; called by muse, mutect2, varscan2
- STYXL2 | c.1399C>A p.R467S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as COSV54801761, COSV99608449; called by muse, mutect2, varscan2
- SYNE3 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100515566; called by muse, mutect2
- SYNJ2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778616482, COSV62895357; called by muse, mutect2, varscan2
- THSD4 | c.2428T>G p.C810G | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99964176; called by muse, mutect2, varscan2
- TMEM200A | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV51661225, COSV99758550, COSV99758827; called by muse, mutect2, varscan2
- TTN | c.93115G>A p.A31039T (on ENST00000591111; = p.A23615T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/372 reads (3%) | PolyPhen probably damaging (0.964); catalogued as rs1340922711, COSV100591243; called by muse, mutect2
- UNC79 | c.3719C>A p.A1240E (on ENST00000393151 / NM_001346218.2; = p.A1063E on NM_020818.5) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV56395989, COSV99825398; called by muse, mutect2, varscan2
- USP10 | c.709A>T p.R237W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV99551037; called by muse, mutect2, varscan2
- ZNF333 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99468700; called by muse, mutect2, varscan2
- ZNF556 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV100298508; called by muse, mutect2, varscan2
- ZNF99 | c.2446T>C p.S816P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs878954375, COSV68055348; called by muse, mutect2, varscan2
- ZWINT | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 32/165 reads (19%) | catalogued as COSV100571467; called by muse, mutect2, varscan2
- CILK1 | c.1313_1331delinsAT p.S438Nfs*7 (on ENST00000350082 / NM_001375397.1; = p.S431Nfs*7 on NM_014920.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 56/176 reads (32%) | called by pindel, varscan2*
- FAM229B | c.146del p.G49Efs*5 | Frame Shift Del (DEL) | VAF 58/128 reads (45%) | called by mutect2, pindel, varscan2
- FAT1 | c.11952del p.Q3985Rfs*5 | Frame Shift Del (DEL) | VAF 81/201 reads (40%) | called by mutect2, pindel, varscan2
- FCGBP | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- KCNS3 | c.247dup p.Y83Lfs*32 | Frame Shift Ins (INS) | VAF 47/270 reads (17%) | called by mutect2, pindel, varscan2
- NBPF26 | c.2189A>G p.K730R (on ENST00000620612; = p.K468R on NM_001351372.1) | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- OSBPL3 | c.361del p.E121Sfs*6 | Frame Shift Del (DEL) | VAF 43/161 reads (27%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.974del p.I325Tfs*23 | Frame Shift Del (DEL) | VAF 60/168 reads (36%) | called by mutect2, pindel, varscan2
- POU6F2 | c.111_112del p.S38Rfs*6 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- RIN1 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2
- WDR90 | c.3986_3996del p.R1329Lfs*9 | Frame Shift Del (DEL) | VAF 53/159 reads (33%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2533C>T p.Q845* | Nonsense Mutation (SNP) | VAF 67/179 reads (37%) | called by muse, mutect2, varscan2
- ABCG8 | c.222C>A p.P74= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV99699371; called by muse, mutect2, varscan2
- ACSL5 | c.93G>C p.L31= (on ENST00000354273; = p.L87= on NM_016234.3) | Silent (SNP) | VAF 51/240 reads (21%) | catalogued as COSV100634431; called by muse, mutect2, varscan2
- ATP4A | c.36G>A p.V12= | Silent (SNP) | VAF 183/314 reads (58%) | catalogued as COSV99382024; called by muse, mutect2, varscan2
- CDH23 | c.6669G>T p.L2223= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99818453; called by muse, mutect2, varscan2
- CLCN1 | c.2412C>A p.A804= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100577632; called by muse, mutect2
- CSMD3 | c.10170A>G p.T3390= (on ENST00000297405 / NM_001363185.1; = p.T3221= on NM_052900.3) | Silent (SNP) | VAF 73/157 reads (46%) | catalogued as COSV99822129; called by muse, varscan2
- CTAGE6 | c.1269C>G p.L423= | Silent (SNP) | VAF 76/505 reads (15%) | catalogued as COSV101417797; called by muse, mutect2, varscan2
- DCAF4L2 | c.855G>C p.L285= | Silent (SNP) | VAF 72/210 reads (34%) | catalogued as COSV60478246; called by muse, mutect2, varscan2
- DOCK11 | c.1509A>T p.V503= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99352711; called by muse, mutect2
- DSP | c.1491C>T p.G497= | Silent (SNP) | VAF 124/312 reads (40%) | catalogued as COSV101131162, COSV65795063; called by muse, mutect2, varscan2
- FAM180A | c.378A>T p.T126= | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as COSV100647201; called by muse, mutect2, varscan2
- FRG2 | c.585A>T p.A195= | Silent (SNP) | VAF 108/208 reads (52%) | called by muse, mutect2, varscan2
- KCNMA1 | c.3654G>T p.R1218= (on ENST00000286628 / NM_001161352.2; = p.R1160= on NM_002247.4) | Silent (SNP) | VAF 140/388 reads (36%) | catalogued as COSV99694478; called by muse, mutect2, varscan2
- LAMA2 | c.6075T>A p.A2025= | Silent (SNP) | VAF 58/114 reads (51%) | catalogued as COSV101369856; called by muse, mutect2, varscan2
- LAMB3 | c.1998G>A p.Q666= | Silent (SNP) | VAF 48/220 reads (22%) | catalogued as COSV100620057; called by muse, mutect2, varscan2
- MAP1A | c.366C>T p.D122= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV100287963; called by muse, mutect2, varscan2
- MAP4K3 | c.2343A>G p.Q781= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as rs1199487668, COSV99809819; called by muse, mutect2, varscan2
- MRAP2 | c.96A>T p.P32= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as COSV100004577; called by muse, mutect2, varscan2
- MYO18B | c.6768G>C p.G2256= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100122393; called by muse, mutect2, varscan2
- NLRP2 | c.126C>T p.I42= | Silent (SNP) | VAF 72/122 reads (59%) | catalogued as rs371737471; called by muse, mutect2, varscan2
- NRXN1 | c.3519C>A p.G1173= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV100452782; called by muse, mutect2, varscan2
- NRXN3 | c.1473C>A p.P491= (on ENST00000335750 / NM_001330195.2; = p.P118= on NM_004796.6) | Silent (SNP) | VAF 43/239 reads (18%) | catalogued as COSV100199933; called by muse, mutect2, varscan2
- OR2C1 | c.411C>T p.N137= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs1315044777, COSV100514817, COSV59241314; called by muse, mutect2, varscan2
- OR6B1 | c.618C>A p.I206= | Silent (SNP) | VAF 100/341 reads (29%) | catalogued as COSV101281629, COSV68770307; called by muse, mutect2, varscan2
- PCDHGA2 | c.228T>C p.A76= | Silent (SNP) | VAF 76/151 reads (50%) | catalogued as COSV99529021; called by muse, mutect2, varscan2
- PSMB3 | c.330C>T p.A110= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as rs752478547; called by muse, mutect2, varscan2
- PTCHD3 | c.630G>T p.S210= | Silent (SNP) | VAF 99/213 reads (46%) | catalogued as COSV101438806, COSV71256802; called by muse, mutect2, varscan2
- RNF213 | c.358C>T p.L120= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV100172888; called by muse, mutect2, varscan2
- SCAMP5 | c.444G>T p.A148= | Silent (SNP) | VAF 167/323 reads (52%) | catalogued as rs774185903, COSV100723776; called by muse, mutect2, varscan2
- SEMA6A | c.525A>T p.A175= | Silent (SNP) | VAF 56/101 reads (55%) | catalogued as COSV99962705; called by muse, mutect2, varscan2
- SLC9A4 | c.1254C>T p.I418= | Silent (SNP) | VAF 47/246 reads (19%) | catalogued as COSV99762627; called by muse, mutect2, varscan2
- SORCS2 | c.2442C>G p.T814= | Silent (SNP) | VAF 105/324 reads (32%) | catalogued as COSV100211214; called by muse, mutect2, varscan2
- STAP1 | c.327G>A p.G109= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs910327862, COSV99609089; called by muse, mutect2, varscan2
- STAU1 | c.399G>T p.V133= (on ENST00000371856 / NM_001319135.1; = p.V52= on NM_004602.3) | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as COSV100574219; called by muse, mutect2, varscan2
- STK36 | c.3429G>T p.L1143= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV99830917; called by muse, mutect2, varscan2
- TMCC3 | c.621C>A p.A207= | Silent (SNP) | VAF 87/184 reads (47%) | catalogued as COSV99705130; called by muse, mutect2, varscan2
- TMEM185A | c.141A>T p.I47= | Silent (SNP) | VAF 257/380 reads (68%) | catalogued as COSV100382917; called by muse, mutect2, varscan2
- TRAPPC9 | c.1959G>T p.T653= | Silent (SNP) | VAF 49/191 reads (26%) | catalogued as rs1266080217, COSV66908030; called by muse, mutect2, varscan2
- ZNF526 | c.303G>T p.V101= | Silent (SNP) | VAF 86/137 reads (63%) | catalogued as COSV100004294; called by muse, mutect2, varscan2
- ADA2 | c.753+3999A>T | Intron (SNP) | VAF 44/87 reads (51%) | catalogued as COSV99375668; called by muse, mutect2, varscan2
- LRP5L | n.410G>T | RNA (SNP) | VAF 61/137 reads (45%) | catalogued as COSV101292705; called by muse, mutect2, varscan2
- MGAM | c.4618+1937G>T | Intron (SNP) | VAF 39/57 reads (68%) | catalogued as COSV101527352; called by muse, mutect2, varscan2
- NBPF25P | n.1165C>A | RNA (SNP) | VAF 370/803 reads (46%) | called by muse, mutect2, varscan2
- PKD1L2 | n.3087G>A | RNA (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- SNORD114-19 | n.21C>A | RNA (SNP) | VAF 35/203 reads (17%) | called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+561G>C | Intron (SNP) | VAF 24/114 reads (21%) | catalogued as COSV72102883; called by muse, mutect2, varscan2
- TUBB7P | n.678C>A | RNA (SNP) | VAF 8/38 reads (21%) | catalogued as rs1400959412; called by mutect2, varscan2
- XIRP2 | c.*96_*97insC | 3'UTR (INS) | VAF 18/111 reads (16%) | catalogued as COSV99737474; called by mutect2, pindel, varscan2
